Somatic mutation profile of tumor specimen C3L-00674-71 (aliquot CPT0064650009) from CPTAC case C3L-00674, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 45.6 years (16,667 days).
Specimen C3L-00674-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c51ffeb6-bf8b-42de-867f-87dc112ed0e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00674-31 (Blood Derived Normal), aliquot CPT0066670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80ed60e5-a141-4403-b687-949764e13c86

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Nonsense Mutation 5, RNA 1, 3'UTR 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSG1 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 124/511 reads (24%) | catalogued as rs568609861, COSV57134949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDR | c.3094C>T p.R1032* | Nonsense Mutation (SNP) | VAF 81/380 reads (21%) | hotspot (GDC flag); catalogued as rs767542615, COSV55758800; called by muse, mutect2, varscan2
- MLPH | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 125/579 reads (22%) | catalogued as rs140470472; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 95/351 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs786204859, CD110173, CM983501, COSV64288670, COSV64294671; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACCSL | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 77/335 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.206); catalogued as rs371463744; called by muse, mutect2, varscan2
- CUX2 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55635400; called by muse, mutect2, varscan2
- DOCK6 | c.5542C>T p.R1848C | Missense Mutation (SNP) | VAF 116/613 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs746066363, COSV53914237; called by muse, mutect2, varscan2
- EGFR | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 52/1533 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51774829, COSV51792876; called by muse, mutect2
- ENPP2 | c.1426G>A p.G476R (on ENST00000075322 / NM_001040092.3; = p.G528R on NM_006209.5) | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1307029342, COSV50027006; called by muse, mutect2, varscan2
- GRIN3B | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs771883513; called by muse, mutect2, varscan2
- HTR3C | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs147427211; called by muse, mutect2, varscan2
- HYDIN | c.11305C>T p.R3769* | Nonsense Mutation (SNP) | VAF 40/179 reads (22%) | catalogued as rs746719490, COSV101124773; called by muse, mutect2, varscan2
- INPP4A | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50811767; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1230887539; called by muse, mutect2
- KCNN1 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as rs1250560986; called by muse, mutect2, varscan2
- LRP2 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.06); catalogued as rs548624353, COSV55574384; called by muse, mutect2, varscan2
- MMP8 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs562264919, COSV52632495; called by muse, mutect2, varscan2
- OLR1 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 55/235 reads (23%) | catalogued as rs374394285; called by muse, mutect2, varscan2
- PGAP4 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs372713797; called by muse, mutect2, varscan2
- PROKR2 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 138/528 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370738961, CM1010043; called by muse, mutect2, varscan2
- RIMBP2 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs762190421, COSV55468028; called by muse, mutect2, varscan2
- TPRX1 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1038689820; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs763657437; called by muse, mutect2, varscan2
- WDR90 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1378701335, COSV53471209; called by muse, mutect2, varscan2
- XIRP2 | c.850G>A p.V284I (on ENST00000628543; = p.V459I on NM_152381.6) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs546227545, COSV104401437; called by muse, mutect2, varscan2
- ZNF827 | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 51/340 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs778669248; called by muse, mutect2, varscan2
- DSC1 | c.1955A>G p.H652R | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.991); called by muse, varscan2
- EGFL6 | c.1394T>C p.L465P | Missense Mutation (SNP) | VAF 129/273 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- LCK | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- MAGEC1 | c.3322A>G p.K1108E | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- MUC4 | c.3539G>T p.G1180V | Missense Mutation (SNP) | VAF 68/487 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, varscan2
- NAALADL2 | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- PUM1 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, varscan2
- RPL5 | c.545G>C p.G182A | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- SEMA3D | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TG | c.6391_6394del p.L2131Rfs*21 | Frame Shift Del (DEL) | VAF 66/350 reads (19%) | called by mutect2, pindel, varscan2
- TMEM151A | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- UTRN | c.6329G>T p.R2110I | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- BFSP1 | c.888G>A p.A296= | Silent (SNP) | VAF 62/381 reads (16%) | catalogued as rs749513994, COSV100925375; called by muse, mutect2, varscan2
- BICRA | c.720G>A p.Q240= | Silent (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- C10orf71 | c.4134C>T p.H1378= | Silent (SNP) | VAF 50/166 reads (30%) | called by muse, mutect2, varscan2
- FAT2 | c.3540C>T p.N1180= | Silent (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- FREM3 | c.1086C>T p.Y362= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs1462201880; called by muse, mutect2, varscan2
- GPR6 | c.936C>T p.Y312= | Silent (SNP) | VAF 56/243 reads (23%) | catalogued as rs772897264, COSV51571538; called by muse, mutect2, varscan2
- MATK | c.549C>T p.A183= (on ENST00000310132 / NM_139355.3; = p.A184= on NM_002378.4) | Silent (SNP) | VAF 45/195 reads (23%) | catalogued as rs953614684, COSV59556313; called by muse, mutect2, varscan2
- PSG3 | c.525C>T p.D175= | Silent (SNP) | VAF 56/553 reads (10%) | catalogued as rs568127706, COSV59503716; called by muse, mutect2, varscan2
- SDAD1 | c.336C>T p.L112= | Silent (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- SLC26A8 | c.480C>T p.N160= | Silent (SNP) | VAF 44/150 reads (29%) | catalogued as rs373715763; called by muse, mutect2, varscan2
- SYNE1 | c.15444A>G p.L5148= (on ENST00000367255 / NM_182961.4; = p.L5077= on NM_033071.3) | Silent (SNP) | VAF 102/428 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.85248T>C p.D28416= (on ENST00000591111; = p.D20992= on NM_003319.4) | Silent (SNP) | VAF 70/323 reads (22%) | catalogued as rs774509104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V0A4 | c.*21C>T | 3'UTR (SNP) | VAF 86/494 reads (17%) | catalogued as rs770534833; called by muse, mutect2, varscan2
- MEIOC | c.-57C>T | 5'UTR (SNP) | VAF 3/30 reads (10%) | catalogued as COSV63439629; called by muse, mutect2
- SPAG16-DT | n.359C>T | RNA (SNP) | VAF 15/66 reads (23%) | catalogued as rs771866583; called by muse, mutect2, varscan2
